Somatic mutation profile of tumor specimen TCGA-DD-AAVR-01A (aliquot TCGA-DD-AAVR-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVR, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 44.2 years (16,157 days).
Specimen TCGA-DD-AAVR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60860123-e058-49b2-ade2-9f65b85c2770.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVR-10A (Blood Derived Normal), aliquot TCGA-DD-AAVR-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fecd9d3-17e7-4188-8c6c-ca147b4c9d8a

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 19, Nonsense Mutation 4, In Frame Del 2, Splice Region 2, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG1L | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs200222793, COSV100444792; called by muse, mutect2
- ATP2B2 | c.1543G>A p.D515N (on ENST00000352432; = p.D481N on NM_001683.5) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.36); catalogued as rs202118324; called by muse, mutect2, varscan2
- BAP1 | c.2131A>T p.K711* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV56238044, COSV99964016; called by muse, mutect2, varscan2
- BAP1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553646045, COSV56235364, COSV56236836, COSV56242037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.2468G>T p.G823V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600661; called by muse, mutect2, varscan2
- BCL11B | c.2242G>A p.G748S (on ENST00000357195 / NM_001282237.2; = p.G677S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV61739173; called by muse, mutect2, varscan2
- BNIPL | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99764666; called by muse, mutect2, varscan2
- BRSK1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1405017626, COSV58668080; called by muse, mutect2, varscan2
- CHRNA7 | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100181249; called by muse, mutect2, varscan2
- CS | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100673240; called by muse, mutect2, varscan2
- CYLC1 | c.140A>T p.D47V | Missense Mutation (SNP) | VAF 180/366 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100254695; called by muse, mutect2, varscan2
- ELN | c.165G>A p.A55= | Splice Region (SNP) | VAF 23/95 reads (24%) | catalogued as rs376512299; called by muse, mutect2, varscan2
- EVC | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99381819; called by muse, mutect2, varscan2
- FBLN7 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV100485563; called by muse, mutect2, varscan2
- FGF16 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV101466318; called by muse, mutect2, varscan2
- FRMPD4 | c.573G>A p.S191= | Splice Region (SNP) | VAF 47/97 reads (48%) | catalogued as rs771325062, COSV66213621, COSV66219825; called by muse, mutect2, varscan2
- FSHR | c.1080G>T p.M360I | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100437240, COSV58633933; called by muse, mutect2
- FURIN | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs962905822, COSV99184686; called by muse, mutect2, varscan2
- GATB | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs749000969, COSV56131994; called by muse, mutect2, varscan2
- GFM2 | c.2046T>G p.D682E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99714374; called by muse, mutect2, varscan2
- GNAZ | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.849); catalogued as COSV50742211, COSV99320808; called by muse, mutect2, varscan2
- GPRIN3 | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV100310760; called by muse, mutect2, varscan2
- GTF2E1 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99381965; called by muse, mutect2, varscan2
- KLHL32 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100987143, COSV100987309; called by muse, mutect2, varscan2
- MAP4K2 | c.725G>T p.W242L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99580999; called by muse, mutect2, varscan2
- MED14 | c.3221A>G p.H1074R | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV100247486; called by muse, mutect2, varscan2
- METAP2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV99704824; called by muse, mutect2, varscan2
- MUCL3 | c.1333C>T p.P445S (on ENST00000304311; = p.P1321S on NM_080870.4) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100423859, COSV58516538; called by muse, mutect2, varscan2
- NFXL1 | c.2653C>T p.Q885* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs565045894, COSV101040365; called by muse, mutect2, varscan2
- OR4A47 | c.629T>A p.L210Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV101487067; called by muse, mutect2, varscan2
- OR4D6 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100271714; called by muse, mutect2, varscan2
- OVOL1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100256700; called by muse, mutect2, varscan2
- PCDH11Y | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99291559; called by muse, mutect2, varscan2
- PCIF1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100976066; called by muse, mutect2, varscan2
- PLB1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV59820852; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 31/146 reads (21%) | catalogued as rs1565550899; called by mutect2, varscan2
- RBBP4 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100995660; called by muse, mutect2, varscan2
- RCSD1 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100827664; called by muse, mutect2, varscan2
- RPL5 | c.177T>A p.D59E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100240380; called by muse, mutect2, varscan2
- RWDD2B | c.701G>C p.S234T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV99725620; called by muse, mutect2, varscan2
- SBF1 | c.4783A>T p.N1595Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100817764; called by muse, mutect2, varscan2
- SF3B3 | c.3511A>T p.K1171* | Nonsense Mutation (SNP) | VAF 32/63 reads (51%) | catalogued as COSV100209943; called by muse, mutect2, varscan2
- SIM2 | c.1167+2T>C p.X389_splice | Splice Site (SNP) | VAF 23/129 reads (18%) | catalogued as COSV99293280; called by muse, mutect2, varscan2
- TEX33 | c.589G>A p.D197N (on ENST00000381821 / NM_001163857.2; = p.D112N on NM_178552.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV101111491; called by muse, mutect2, varscan2
- TNFRSF10C | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); catalogued as rs953312122, COSV100790523; called by muse, varscan2
- TRPS1 | c.3335G>A p.R1112Q (on ENST00000220888 / NM_001330599.2; = p.R1125Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773593651, COSV55261368; called by muse, mutect2, varscan2
- UBR2 | c.4004G>A p.S1335N | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100867451; called by muse, mutect2, varscan2
- USP40 | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs368100283; called by muse, mutect2, varscan2
- XIRP2 | c.5099T>C p.L1700P (on ENST00000628543; = p.L1875P on NM_152381.6) | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99743235; called by muse, mutect2, varscan2
- ZBTB46 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99829210; called by muse, mutect2, varscan2
- CAPG | c.910_912del p.K304del | In Frame Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- EIF3J | c.572-4_587del p.X191_splice | Splice Site (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- H1-4 | c.151_153del p.S51del | In Frame Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- NEB | c.12302del p.K4101Rfs*51 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- ARID2 | c.1143T>G p.L381= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100536271; called by muse, mutect2, varscan2
- ASB17 | c.192C>T p.D64= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs534539433, COSV52409592; called by muse, mutect2, varscan2
- CCDC54 | c.282C>A p.V94= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99660214, COSV99660230; called by muse, mutect2, varscan2
- COL16A1 | c.3486C>T p.G1162= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1427003784, COSV99594546; called by muse, mutect2, varscan2
- COL2A1 | c.2256T>G p.P752= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100476537; called by muse, mutect2, varscan2
- DYNC2H1 | c.3675A>G p.L1225= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as COSV100518678; called by muse, mutect2, varscan2
- ERBB2 | c.1911G>A p.L637= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV99508016; called by muse, mutect2, varscan2
- H4C3 | c.24A>T p.G8= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs763181691, COSV100619555; called by muse, mutect2, varscan2
- HTT | c.7965T>C p.S2655= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100750812; called by muse, mutect2, varscan2
- KATNIP | c.1086G>A p.K362= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99851170; called by muse, mutect2, varscan2
- RAB39B | c.195C>T p.T65= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV65625413; called by muse, mutect2, varscan2
- RAB5C | c.609G>A p.Q203= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99863559; called by muse, mutect2, varscan2
- RFX5 | c.519A>T p.P173= | Silent (SNP) | VAF 46/225 reads (20%) | catalogued as COSV100923882; called by muse, mutect2, varscan2
- RIN2 | c.1281C>T p.S427= (on ENST00000255006 / NM_001242581.1; = p.S378= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/658 reads (7%) | catalogued as rs370646119; called by muse, mutect2
- SETX | c.1947A>C p.P649= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99809890; called by muse, mutect2, varscan2
- SH3PXD2B | c.2055C>T p.G685= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100288035; called by muse, mutect2, varscan2
- TMEM245 | c.180G>T p.V60= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV101002330; called by muse, mutect2, varscan2
- ZC3H13 | c.1131T>C p.H377= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99668202; called by muse, mutect2, varscan2
- ZNF804B | c.1263C>T p.S421= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100303965, COSV60830250; called by muse, mutect2, varscan2
- NBEA | c.7618-340G>T | Intron (SNP) | VAF 38/190 reads (20%) | catalogued as COSV100080543; called by muse, mutect2, varscan2
